Somatic mutation profile of tumor specimen TCGA-DB-A4XB-01A (aliquot TCGA-DB-A4XB-01A-11D-A26M-08) from TCGA case TCGA-DB-A4XB, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Occipital lobe; Tumor grade: G3; Age at diagnosis: 38.3 years (13,990 days).
Specimen TCGA-DB-A4XB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1825e190-0c5d-4f53-9824-3c3df6470895.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4XB-10A (Blood Derived Normal), aliquot TCGA-DB-A4XB-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41ee2fb1-1616-4d88-a32c-cfe48d4e4171

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 22, Silent 5, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 12/14 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63309310, COSV63309316; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SDHA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1061517, CM000423, CM165649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 50/58 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKS1A | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs753878171, COSV64459712; called by muse, mutect2
- CATSPERB | c.2456C>T p.T819M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs748919841, COSV56424329; called by muse, mutect2, varscan2
- CEP162 | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV57618839; called by muse, mutect2
- CNTN4 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.761); catalogued as COSV61870557; called by muse, mutect2, varscan2
- DIO2 | c.706C>G p.Q236E | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV70444997, COSV70445592; called by muse, varscan2
- ECT2 | c.95A>T p.E32V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV51687431; called by muse, mutect2
- FERMT2 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV58406093; called by muse, mutect2, varscan2
- FTH1 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV56444967; called by muse, mutect2, varscan2
- HKDC1 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs148336562; called by muse, mutect2, varscan2
- KIF24 | c.3440A>G p.E1147G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.276); catalogued as COSV52658193; called by muse, mutect2, varscan2
- LIFR | c.542G>C p.S181T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1379549094, COSV54687406; called by muse, mutect2, varscan2
- NOS1 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as COSV57609657; called by muse, mutect2, varscan2
- OR8J3 | c.338T>C p.M113T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs753102892, COSV56879977; called by muse, mutect2, varscan2
- PTPRCAP | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs572090784, COSV57048595; called by muse, mutect2, varscan2
- RAB23 | c.524A>T p.Q175L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV58097594; called by muse, mutect2, varscan2
- SCLY | c.1021A>G p.R341G (on ENST00000651534; = p.R333G on NM_016510.7) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV54540757; called by muse, mutect2, varscan2
- SPATA31D1 | c.4052G>T p.R1351I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV61194255; called by muse, mutect2, varscan2
- TPM2 | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV61405465; called by muse, mutect2, varscan2
- TRRAP | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV62841925; called by muse, mutect2, varscan2
- OR2M3 | c.546del p.S183Pfs*3 | Frame Shift Del (DEL) | VAF 38/184 reads (21%) | called by mutect2, pindel, varscan2
- CPXM1 | c.1797C>T p.H599= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs775234521, COSV66045022; called by muse, mutect2, varscan2
- FLNC | c.2514G>A p.A838= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs762824697, COSV57953277; called by muse, mutect2, varscan2
- HADHA | c.810G>A p.A270= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs376632479; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLG | c.2226C>T p.T742= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs1189462435, COSV57514313; called by muse, mutect2, varscan2
- PTPRD | c.246C>T p.L82= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV61936796; called by muse, mutect2, varscan2
